CPTAC case C3L-02651 — Larynx — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Larynx. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3ef779a0-457a-4045-b04c-191b734b81a4

Demographics
Sex at birth: male; Race: white; Year of birth: 1937; Vital status: Alive; Country of birth: Bulgaria.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Larynx, NOS; Site of resection or biopsy: Larynx, NOS; Age at diagnosis: 81.5 years (29,752 days); Year of diagnosis: 2018; AJCC staging edition: 8th; AJCC clinical M: MX; AJCC pathologic T: T2; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage II; Tumor grade: G2; Residual disease: RX; Days to last known disease status: 291 days; Days to last follow up: 291 days; Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 2.5 cm (a second GDC size field records 4.5 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymphatic invasion present: No; Margin status: Uninvolved; Perineural invasion present: No; Vascular invasion present: No.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 291.

Other clinical attributes
- Weight: 70 kg; Height: 183 cm; BMI: 20.9.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 78; Cigarettes per day: 30; Tobacco smoking onset year: 1966; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 56.

Biospecimens (6 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02651-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -10 days; Initial weight: 101 mg; Time between excision and freezing: 21 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02651-24: Section location: Larynx; Percent tumor nuclei: 80; Percent necrosis: 5.
- Sample C3L-02651-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -10 days; Initial weight: 110 mg; Time between excision and freezing: 21 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02651-25: Section location: Larynx; Percent tumor nuclei: 85; Percent necrosis: 5.
- Sample C3L-02651-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -10 days; Initial weight: 50 mg; Time between excision and freezing: 23 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-02651-07: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -10 days; Initial weight: 60 mg; Time between excision and freezing: 23 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-02651-08: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -10 days; Initial weight: 70 mg; Time between excision and freezing: 23 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-02651-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -10 days; Method of sample procurement: Blood Draw.
